Somatic mutation profile of tumor specimen ALCH-B4AR-TTP1-A (aliquot ALCH-B4AR-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4AR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 67.6 years (24,679 days).
Specimen ALCH-B4AR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3a75c97-2be1-49b7-bd27-910dc50a1c09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4AR-NB1-A (Blood Derived Normal), aliquot ALCH-B4AR-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23e47a10-6cc7-4d57-b2f4-8c27f4af3d94

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, Nonsense Mutation 2, Intron 2, Frame Shift Del 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2500G>T p.V834L | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs397517127, COSV51767386, COSV51777202; ClinVar: pathogenic; called by muse, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 38/333 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, varscan2
- TP53 | c.782+1G>T p.X261_splice | Splice Site (SNP) | VAF 21/104 reads (20%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- CCDC7 | c.3463G>A p.A1155T | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.269); catalogued as COSV56541193; called by muse, mutect2, varscan2
- FAAP100 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1174991749; called by muse, mutect2
- IGHV3-15 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.057); catalogued as rs552580648; called by muse, mutect2, varscan2
- IRF6 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 20/477 reads (4%) | catalogued as COSV65418665; called by muse, mutect2
- OR13C8 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs767536072; called by muse, mutect2
- OR8G2P | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.292); catalogued as rs1276892398; called by muse, mutect2, varscan2
- PSME1 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757143981; called by muse, mutect2, varscan2
- PTEN | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 30/345 reads (9%) | catalogued as rs1554825210, COSV64291584, COSV64299810; called by muse, mutect2
- ZBTB8B | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs1301500785, COSV72152296; called by muse, mutect2, varscan2
- BCORL1 | c.2623C>G p.L875V | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DLG2 | c.2144C>A p.P715Q | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.171); called by muse, mutect2
- KLHL21 | c.1499del p.Q500Rfs*31 | Frame Shift Del (DEL) | VAF 17/136 reads (13%) | called by mutect2, pindel, varscan2
- PDCD10 | c.521T>C p.F174S | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PELI3 | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- RNPC3 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SELL | c.369A>C p.E123D (on ENST00000650983; = p.E110D on NM_000655.5) | Missense Mutation (SNP) | VAF 55/416 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TMCO4 | c.68A>C p.E23A | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBA1 | c.2603T>C p.L868P | Missense Mutation (SNP) | VAF 45/420 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3H8 | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZKSCAN2 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2
- ZNF75D | c.118A>C p.I40L | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN2 | c.1779A>T p.K593N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- MAGEB17 | c.342C>T p.G114= | Silent (SNP) | VAF 13/133 reads (10%) | catalogued as rs1432806844; called by muse, mutect2
- MMP16 | c.1269C>T p.Y423= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as rs1357678331, COSV54162612; called by muse, mutect2
- SLCO3A1 | c.309G>A p.G103= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV59231747; called by muse, mutect2
- TTC6 | c.690C>T p.F230= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs763092362; called by mutect2, varscan2
- COL5A1 | c.5136+99C>T | Intron (SNP) | VAF 24/108 reads (22%) | catalogued as rs765218878; called by muse, mutect2, varscan2
- RGS14 | c.628-43G>T | Intron (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- SMPX | c.-172C>T | 5'UTR (SNP) | VAF 13/340 reads (4%) | catalogued as rs1392833668; called by muse, mutect2
